Gene-level copy-number profile of tumor specimen REBC-AF8N-TTP1 from REBC case REBC-AF8N, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-AF8N-TTP1: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9d77217b-75a4-45f7-9cb4-52fa37cc7687.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-AF8N-NB1-SC208348 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/b554e08a-8b2b-49ad-ac96-5bea174e6504

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 215; copy number 2: 57,487; copy number 3: 665.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,418,210–158,426,237, 1 gene: OR10K2.
- chr1:194,488,103–194,488,205, 1 gene: RNU6-983P.
- chr5:45,890,216–45,895,970, 1 gene: AC122694.1.
- chr6:22,589,137–22,593,833, 1 gene: AL033539.1.
- chr6:29,137,410–29,142,934, 1 gene: AL645937.1.
- chr7:9,621,764–9,769,513, 1 gene (within-gene range 0–2): AC060834.2.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr8:46,822,174–46,907,309, 7 genes (within-gene range 0–1): LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3.
- chr11:5,856,674–5,857,734, 1 gene (within-gene range 0–2): OR52E8.
- chr11:48,880,111–48,951,895, 5 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5, TRIM51CP.
- chr11:58,796,237–58,796,854, 1 gene: TMA16P1.
- chr11:59,391,354–59,392,292, 1 gene: OR5BB1P.
- chr16:52,198,012–52,227,956, 1 gene: AC007333.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
